Somatic mutation profile of tumor specimen 0DEYDU from CCDI case PBBRDE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.5 years (2,011 days).
Specimen 0DEYDU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e348b92-9cb4-434c-a25a-7e3dad34a545.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEYDL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc41c42a-165a-4077-a4f5-8ee44106f9bb

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GAS2L1 | c.1196C>G p.P399R | Missense Mutation (SNP) | VAF 174/349 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV53330353; called by muse, mutect2, varscan2
- IGSF5 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 273/729 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as rs765181728, COSV66029470; called by muse, mutect2, varscan2
- ACBD4 | c.209+1G>T p.X70_splice | Splice Site (SNP) | VAF 14/346 reads (4%) | called by muse, mutect2
- NBEA | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 28/847 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- RBM4 | c.529_536dup p.S180* | Frame Shift Ins (INS) | VAF 117/316 reads (37%) | called by mutect2, varscan2
- VWA3A | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 287/687 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- LATS2 | c.900C>T p.A300= | Silent (SNP) | VAF 89/305 reads (29%) | catalogued as rs762614289; called by muse, mutect2, varscan2
- MYO15A | c.930C>T p.D310= | Silent (SNP) | VAF 51/718 reads (7%) | catalogued as rs774380947, COSV52757868; called by muse, mutect2
